Gene-level copy-number profile of tumor specimen TCGA-26-6173-01A from TCGA case TCGA-26-6173, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-26-6173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.009e38eb-6d65-4dee-93a5-9d0ba10f66ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-26-6173-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bce757ec-896a-497e-ad57-0b729a9738ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 8,773; copy number 2: 41,361; copy number 3: 9,583; copy number 4: 30; copy number 5: 14; copy number 45: 16; copy number 46: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-26-6173-01A-11D-1842-01): tumor purity 0.57, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,341,685–88,584,530, 25 genes (within-gene range 0–1): LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,385,829–18,388,514, 1 gene, copy number 5: AL591896.1.
- chr2:218,200,434–218,368,099, 13 genes, copy number 46: HMGB1P9, ARPC2, AC021016.1, GPBAR1, AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1.
- chr7:54,542,325–55,344,958, 16 genes, copy number 45: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr7:87,934,143–88,756,725, 13 genes, copy number 5 (within-gene range 3–5): ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28.

Autosomal genes at a single copy (total copy number 1): 6,397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
